Gene-level copy-number profile of tumor specimen TCGA-C5-A8ZZ-01A from TCGA case TCGA-C5-A8ZZ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 41.8 years (15,262 days).
Specimen TCGA-C5-A8ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.dffe3861-733c-45ed-9a54-56695803762d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A8ZZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c82d2426-79db-4b91-b33c-08a549ae1e09

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,167; copy number 2: 46,607; copy number 3: 6,362; copy number 4: 4; copy number 5: 392; copy number 6: 11; copy number 10: 11; copy number 11: 234; copy number 14: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A8ZZ-01A-11D-A37M-01): tumor purity 0.7, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 673 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,691,681–84,692,591, 1 gene, copy number 6: AC117482.1.
- chr3:88,601,061–90,261,708, 11 genes, copy number 10: NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:132,721,750–137,536,142, 69 genes, copy number 5 (broad region; genes not listed).
- chr3:137,880,295–138,033,655, 3 genes, copy number 6: HSPA8P9, CLDN18, AC016252.1.
- chr3:138,187,248–149,433,274, 178 genes, copy number 5 (broad region; genes not listed).
- chr3:155,240,919–182,985,953, 399 genes, copy number 5–14 (broad region; genes not listed).
- chr3:185,506,262–186,362,234, 12 genes, copy number 5 (within-gene range 3–5): LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG.

Autosomal genes at a single copy (total copy number 1): 6,167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
